TCGA case TCGA-YL-A9WJ — Prostate Adenocarcinoma (TCGA-PRAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Prostate gland; Tissue source site: PROCURE Biobank. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0b5ed938-6ab8-4e76-8558-1d86f3a90dfa

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Canada; Age at index: 47 years; Vital status: Dead; Days to death: 1,855 days (5.1 years); Cause of death: Cancer Related; Cause of death source: Medical Record.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C61; Tissue or organ of origin: Prostate gland; Site of resection or biopsy: Prostate gland; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 47.4 years (17,322 days); Year of diagnosis: 2008; Method of diagnosis: Core Biopsy; AJCC clinical T: T4; AJCC clinical M: M0; AJCC pathologic T: T3b; AJCC pathologic N: N1; Primary gleason grade: Pattern 4; Secondary gleason grade: Pattern 4; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Days to last follow up: 1,855 days (5.1 years); Gleason score: 8.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 10; Tumor level prostate: Apex / Middle; Zone of origin prostate: Overlapping/multiple zones.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 838 days (2.3 years); Days to treatment end: 876 days (2.4 years); Treatment dose: 62 Gy; Number of fractions: 27; Treatment anatomic sites: Locoregional Site.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lymph node, NOS. Age at diagnosis: 51.5 years (18,798 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Head, face or neck, NOS. Age at diagnosis: 51.5 years (18,798 days); Days to diagnosis: 1,476 days (4.0 years); Prior treatment: Yes.

Follow-up (7 entries)
- Day 19 (initial diagnosis): Days to imaging: 19 days; Imaging type: Bone Scan, NOS; Imaging result: Negative.
- Day 21 (initial diagnosis): Days to imaging: 21 days; Imaging type: CT Scan; Imaging anatomic site: Abdomen / Pelvis; Imaging findings: No Evidence of Extraprostatic Extension.
- Day 51 (initial diagnosis): Days to imaging: 51 days; Imaging type: MRI; Imaging findings: Extraprostatic Extension, Localized.
- Days to follow up: 76 days; Progression or recurrence: Yes; Progression or recurrence type: Biochemical; Days to recurrence: 76 days.
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Head, face or neck, NOS; Days to progression: 1,476 days (4.0 years).
- Day 1,476 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 1,476 days (4.0 years).
- Days to follow up: 1,855 days (5.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Prostate-Specific Antigen (PSA): 3.1 ng/mL (day 838).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YL-A9WJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 360 mg.
  Slide TCGA-YL-A9WJ-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YL-A9WJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YL-A9WJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Prostate; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Histologic diagnosis: Prostate Adenocarcinoma Acinar Type; Zone of origin: Overlapping / Multiple Zones; Method initial path diagnosis: Core needle biopsy; Bone scan results: Normal (no evidence of prostate cancer) [cM0]; Ct scan ab pelvis indicator: Yes; Diagnostic mri performed: Yes; Lymph nodes examined: Yes; Cause of death: Prostate Cancer; Biochemical recurrence indicator: Yes.
- Tumor levels: Tumor level: Apex; Tumor level: Middle.
- Diagnostic mri results: Mri results: Extraprostatic Extension Localized (e.g. seminal vesicles).
- Stage record, Psa: PSA most recent results: 3.1.
- Stage record, Gleason grading: Gleason pattern primary: 4; Gleason pattern secondary: 4; Gleason pattern tertiary: 3.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Cause of death: Prostate Cancer; New tumor event type: Distant Metastasis; New tumor event site other: Neck.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,855 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,855 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,476 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YL-A9WJ-01A-11D-A376-01): tumor purity 0.39, ploidy 1.97, whole-genome doublings 0.
